Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8185, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8185-01A (Primary Tumor).

[page 1 of 6]
NEUROPATHOLOGY REPORT

Patient Name: [REDACTED] Sex: M Pathology#: [REDACTED]
Date of Birth: [REDACTED] Date of Collection: [REDACTED]
Patient 1

Copies:

Clinical History: None Given
Pre-Operative Diagnoses: None Given
Post-Operative Diagnosis: None Given
Specimen(s) Submitted: A. Right Frontal Tumor; B. Right Frontal Tumor; C. Right Frontal Pole
CPT Code(s)

FINAL DIAGNOSIS:

- A. Right frontal tumor: Anaplastic astrocytoma, WHO grade 3. See comment.
- B. Right frontal tumor: Anaplastic astrocytoma, WHO grade 3. See comment.
- C. Right frontal pole: Cortex and white matter. No tumor seen.

Comment: This astrocytoma diffusely infiltrates white and gray matter. Some areas are low grade, with a microcystic pattern, others are highly cellular, with abnormal mitoses and marked nuclear pleomorphism. Perineuronal satellitosis is seen, as are microcalcifications. Areas of gemistocytic astrocytoma are present. Some areas have a more monotonous, possibly oligodendroglioma morphology. Many vascular thrombi are seen in small vessels. No vascular endothelial proliferation or necrosis are present (despite extensive sampling, with 51 H&E examined). Immunostain for p53 is positive, supporting an astrocytic neoplasm; Immunostain for MIB-1 shows a nuclear labeling rate of up to 20%, consistent with the diagnosis. Studies for MGMT and 1p19q are in progress.

BRAIN: Resection

MACROSCOPIC

Specimen Type
☒ Resection

For questions regarding this case:

[page 2 of 6]
NEUROPATHOLOGY REPORT

Patient Name:

Pathology #:

Specimen Size

A. 2 pieces of irregular, gray-tan tissue, 0.5 cm each. B. 7.5 x 6.6 x up to 3 cm aggregate C. 6.3 x 3.6 x 3.2 cm

Tumor Site (check all that apply)

☒ Cerebrum: right frontal

Tumor Size

☒ Cannot be determined

MICROSCOPIC

Histologic Type

☒ Anaplastic astrocytoma

Histologic Grade

☒ WHO Grade 3

Margins

☒ Cannot be assessed

*Additional Studies

* ☒ Molecular testing: See above

Intraoperative Consultation:

A. Right frontal mass (SMA):

- Glioblastoma multiforme.

(18 minutes)

Gross Description:

This case has 3 parts, each received fresh and labeled with the patient's name

A. Labeled "right frontal tumor" are 2 pieces of irregular, gray-tan tissue, 0.5 cm each. The specimen is entirely submitted in cassette

B. Labeled "right frontal tumor" is a 54 gram, 7.5 x 6.6 x up to 3 cm aggregate of multiple pieces of gray-tan tissue with a soft, focally hemorrhagic gray-tan cut surface that shows a loss of delineation between gray and white matter and no normal remaining brain parenchyma. Representative sections (to include approximately 50% of specimen) are submitted in cassettes

[page 3 of 6]
NEUROPATHOLOGY REPORT

Patient Name:

Pathology #:

- C. Labeled "right frontal pole" is a 32 gram, 6.3 x 3.6 x 3.2 cm portion of irregular gray-tan tissue consistent with brain cortex. The cut surface shows good delineation between gray and white matter. There is diffuse brown foci throughout the white matter. No discrete lesion is identified. Representative sections (approximately 10% of the specimen) are submitted in cassettes!

Microscopic Description:

51 H&E; MIB1 immunostain

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

Pathologist

[page 4 of 6]
NEUROPATHOLOGY REPORT

Patient Name:
Date of Birth:
Sex: M
Patient 1

Pathology#:
Date of Collection:

Copies:

Clinical History: None Given
Pre-Operative Diagnoses: None Given
Post-Operative Diagnosis: None Given
Specimen(s) Submitted: A. Right Frontal Tumor; B. Right Frontal Tumor; C. Right Frontal Pole
CPT Code(s)

FINAL DIAGNOSIS:

- A. Right frontal tumor: Anaplastic astrocytoma, WHO grade 3. See comment.
- B. Right frontal tumor: Anaplastic astrocytoma, WHO grade 3. See comment.
- C. Right frontal pole: Cortex and white matter. No tumor seen.

Comment: This astrocytoma diffusely infiltrates white and gray matter. Some areas are low grade, with a microcystic pattern, others are highly cellular, with abnormal mitoses and marked nuclear pleomorphism. Perineuronal satellitosis is seen, as are microcalcifications. Areas of gemistocytic astrocytoma are present. Some areas have a more monotonous, possibly oligodendroglioma morphology. Many vascular thrombi are seen in small vessels. No vascular endothelial proliferation or necrosis are present (despite extensive sampling, with 51 H&E examined). Immunostain for p53 is positive, supporting an astrocytic neoplasm; Immunostain for MIB-1 shows a nuclear labeling rate of up to 20%, consistent with the diagnosis. Studies for MGMT and 1p19q are in progress.

BRAIN: Resection

MACROSCOPIC

Specimen Type
X Resection

questions regarding this case:

For

[page 5 of 6]
NEUROPATHOLOGY REPORT

Patient Name:

Pathology #:

Specimen Size

A. 2 pieces of irregular, gray-tan tissue, 0.5 cm each. B. 7.5 x 6.6 x up to 3 cm aggregate C. 6.3 x 3.6 x 3.2 cm

Tumor Site (check all that apply)

☒ Cerebrum: right frontal

Tumor Size

☒ Cannot be determined

MICROSCOPIC

Histologic Type

☒ Anaplastic astrocytoma

Histologic Grade

☒ WHO Grade 3

Margins

☒ Cannot be assessed

*Additional Studies

* ☒ Molecular testing: See above

Intraoperative Consultation:

A. Right frontal mass (SMA):

- Glioblastoma multiforme.

(18 minutes)

Gross Description:

This case has 3 parts, each received fresh and labeled with the patient's name

A. Labeled "right frontal tumor" are 2 pieces of irregular, gray-tan tissue, 0.5 cm each. The specimen is entirely submitted in cassette

B. Labeled "right frontal tumor" is a 54 gram, 7.5 x 6.6 x up to 3 cm aggregate of multiple pieces of gray-tan tissue with a soft, focally hemorrhagic gray-tan cut surface that shows a loss of delineation between gray and white matter and no normal remaining brain parenchyma. Representative sections (to include approximately 50% of specimen) are submitted in cassettes

[page 6 of 6]
NEUROPATHOLOGY REPORT

Patient Name:

Pathology #:

- C. Labeled "right frontal pole" is a 32 gram, 6.3 x 3.6 x 3.2 cm portion of irregular gray-tan tissue consistent with brain cortex. The cut surface shows good delineation between gray and white matter. There is diffuse brown foci throughout the white matter. No discrete lesion is identified. Representative sections (approximately 10% of the specimen) are submitted in cassettes!

Microscopic Description:

51 H&E; MIB1 immunostain

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

Pathologist

Source: NCI Genomic Data Commons file 8f5b62eb-ba7d-4b32-9984-5360d5934fbe (TCGA-FG-8185.74A335AE-A23D-4CC8-ABB1-B8EB6DB90787.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).